CCDI case PBBRXN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a94229e2-afd3-46e2-914a-6827b2b7caa7

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.3 years (6,322 days).

Biospecimens (2 samples)
- Sample 0DFJJ1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFJKV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
